Gene-level copy-number profile of tumor specimen ALCH-AESN-TTP1-A from ALCHEMIST case ALCH-AESN, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.5 years (21,722 days).
Specimen ALCH-AESN-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1ab65216-07c5-48d5-b341-eb6aa16785ab.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AESN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,230 have no estimate.
https://portal.gdc.cancer.gov/files/812ea26c-af95-436e-a9af-8ac982514dce

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 95; copy number 1: 2,696; copy number 2: 53,109; copy number 3: 2,182; copy number 4: 287; copy number 5: 17; copy number 6: 3; copy number 7: 3; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 95 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:176,099,795–176,137,098, 6 genes (within-gene range 0–1): HOXD12, HOXD11, HOXD10, HOXD-AS2, HOXD9, HOXD8.
- chr2:236,153,071–236,153,172, 1 gene: Y_RNA.
- chr2:238,138,668–238,152,947, 1 gene (within-gene range 0–2): KLHL30.
- chr3:9,866,711–9,894,349, 2 genes: CIDEC, JAGN1.
- chr3:75,395,188–75,422,143, 3 genes (within-gene range 0–2): LSP1P2, AC139453.1, ALG1L6P.
- chr4:48,483,343–48,489,526, 1 gene: SLC10A4.
- chr4:182,890,060–182,917,936, 1 gene: DCTD.
- chr5:1,877,413–1,900,493, 3 genes: IRX4, IRX4-AS1, CTD-2194D22.4.
- chr6:18,304,854–18,307,079, 2 genes: AL138825.1, RNU6-263P.
- chr7:155,799,980–155,812,463, 1 gene: SHH.
- chr8:37,908,738–37,966,599, 4 genes: RN7SL709P, GOT1L1, AC144573.1, ADRB3.
- chr9:81,885,496–81,888,985, 2 genes: RNA5SP287, AL158154.1.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr9:127,451,486–127,503,501, 2 genes: LRSAM1, Y_RNA.
- chr10:23,343,957–23,345,181, 1 gene (within-gene range 0–2): AL606469.1.
- chr10:43,077,064–43,130,351, 1 gene: RET.
- chr10:48,009,873–48,060,016, 3 genes: AGAP12P, RNA5SP315, BMS1P7.
- chr10:49,734,641–49,815,562, 3 genes: OGDHL, MAPK6P6, RPL21P89.
- chr14:49,598,761–49,635,244, 8 genes (within-gene range 0–2): LRR1, RHOQP1, AL139099.3, RPL36AL, MGAT2, AL139099.1, DNAAF2, AL139099.2.
- chr14:93,138,066–93,138,465, 1 gene: CYB5AP3.
- chr15:25,169,337–25,184,387, 9 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8.
- chr15:77,976,042–77,993,057, 1 gene (within-gene range 0–4): ADAMTS7P3.
- chr15:77,993,405–77,995,289, 1 gene (within-gene range 0–4): AC104758.1.
- chr16:32,388,135–32,436,203, 1 gene: AC138915.2.
- chr16:32,454,612–32,460,362, 2 genes: AC138915.3, AC138915.1.
- chr16:66,841,433–66,854,153, 2 genes (within-gene range 0–2): AC044802.2, CA7.
- chr16:75,228,181–75,268,053, 2 genes (within-gene range 0–1): BCAR1, AC009078.3.
- chr16:89,268,104–89,273,044, 1 gene (within-gene range 0–3): AC137932.3.
- chr17:82,371,400–82,382,690, 2 genes: UTS2R, AC132938.1.
- chr19:19,515,736–19,546,659, 4 genes: NDUFA13, AC011448.1, YJEFN3, CILP2.
- chr19:54,415,219–54,439,544, 5 genes: TTYH1, AC245884.1, AC245884.9, AC245884.10, AC245884.8.
- chr20:3,071,620–3,094,509, 3 genes: OXT, AVP, RN7SL555P.
- chr20:58,995,185–59,026,654, 2 genes (within-gene range 0–2): CTSZ, TUBB1.
- chr21:10,612,455–13,120,807, 8 genes: SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr21:45,336,707–45,341,990, 2 genes: BX322557.1, LINC00316.
- chr22:23,359,603–23,402,726, 3 genes: CES5AP1, ZDHHC8P1, AP000344.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 24 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:59,974,757–59,975,054, 1 gene, copy number 5: RN7SL475P.
- chr2:241,315,100–241,354,027, 3 genes, copy number 5 (within-gene range 2–5): SEPTIN2, AC104841.1, AC005104.1.
- chr8:43,246,755–43,251,858, 3 genes, copy number 7: AC022616.5, AC022616.7, AC022616.3.
- chr14:36,213,200–36,235,608, 2 genes, copy number 5: AL162511.1, RN7SKP21.
- chr14:104,857,792–104,858,836, 1 gene, copy number 8: AL583810.1.
- chr14:105,583,731–105,588,395, 1 gene, copy number 6: IGHA2.
- chr15:101,903,154–101,979,093, 10 genes, copy number 5: AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr16:975,761–981,596, 1 gene, copy number 5 (within-gene range 2–5): CEROX1.
- chr17:36,103,827–36,110,447, 2 genes, copy number 6: CCL4, RN7SL301P.

Autosomal genes at a single copy (total copy number 1): 2,677. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
